Somatic mutation profile of tumor specimen TARGET-30-PASYMX-01A (aliquot TARGET-30-PASYMX-01A-01D) from TARGET case TARGET-30-PASYMX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.9 years (2,894 days).
Specimen TARGET-30-PASYMX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 249d0a1b-df4f-48f9-887c-6e2054a1bcc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASYMX-10A (Blood Derived Normal), aliquot TARGET-30-PASYMX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2e5f203-44cb-4f67-b3c5-8cf66c71e27f

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52354600; called by muse, mutect2, varscan2
- ADGRA3 | c.2575A>C p.K859Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV51569604; called by muse, mutect2, varscan2
- ALOX15B | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV101205740, COSV66480197, COSV66480315; called by muse, mutect2, varscan2
- AMY2B | c.716C>A p.A239E | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1355391472, COSV63713815; called by muse, mutect2, varscan2
- ARSG | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV71594102; called by muse, mutect2, varscan2
- ATP1A2 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV63406396; called by muse, mutect2, varscan2
- CLSPN | c.2205G>A p.M735I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as rs1282374249, COSV52058261; called by muse, mutect2, varscan2
- ERN1 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV70505310; called by muse, mutect2, varscan2
- FBXL2 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV52143689; called by muse, mutect2, varscan2
- FBXO3 | c.852T>G p.I284M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55768535; called by muse, mutect2, varscan2
- FCRL2 | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV63835520; called by mutect2, varscan2
- KIAA0319 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV65502579; called by muse, mutect2, varscan2
- MAP2K6 | c.734T>G p.I245S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV63008326; called by muse, mutect2, varscan2
- NGEF | c.2027T>C p.I676T | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV50966374; called by muse, mutect2, varscan2
- NPY5R | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58451479, COSV58453367, COSV58454350; called by muse, mutect2, varscan2
- OR2A14 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68718815; called by muse, mutect2, varscan2
- OR9A2 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63307200; called by muse, mutect2, varscan2
- PASD1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.8); PolyPhen benign (0.065); catalogued as COSV64858460; called by mutect2, varscan2
- PITPNM3 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567665348, COSV52601115; called by muse, mutect2, varscan2
- REST | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV58363338; called by muse, mutect2, varscan2
- SRGAP1 | c.393G>C p.Q131H | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV61904691; called by muse, mutect2, varscan2
- TPRG1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV61469608; called by muse, mutect2, varscan2
- TPSD1 | c.197G>A p.C66Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52979098; called by mutect2, varscan2
- ZNF683 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV62876199; called by muse, mutect2, varscan2
- ZDBF2 | c.1292C>A p.S431Y | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, varscan2
- ACVRL1 | c.918G>A p.A306= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV66360341; called by muse, mutect2, varscan2
- B4GALT6 | c.129C>T p.L43= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52705744; called by muse, mutect2, varscan2
- CNN2 | c.108C>A p.T36= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV54049186; called by mutect2, varscan2
- MYH6 | c.564C>A p.T188= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV62455554; called by muse, mutect2, varscan2
- SLAMF6 | c.987C>T p.D329= (on ENST00000368057 / NM_001184714.2; = p.D328= on NM_052931.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV63588509; called by mutect2, varscan2
- TNRC18 | c.8169G>A p.A2723= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1359811661, COSV60307203; called by mutect2, varscan2
- ZC3H13 | c.231A>T p.S77= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, varscan2
